Somatic mutation profile of tumor specimen TCGA-EE-A2M5-06A (aliquot TCGA-EE-A2M5-06A-12D-A197-08) from TCGA case TCGA-EE-A2M5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.2 years (18,340 days).
Specimen TCGA-EE-A2M5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2476a68-70ec-4389-a22a-1dbf5f39e2fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2M5-10A (Blood Derived Normal), aliquot TCGA-EE-A2M5-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e42eb320-7c36-453b-a473-ea0e0f929a94

The open-access MAF lists 2,430 somatic variants for this specimen: 1,564 protein-altering or splice-affecting, 803 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,420, Silent 803, Nonsense Mutation 93, RNA 26, Intron 21, Splice Site 20, Splice Region 17, Frame Shift Del 8, 5'UTR 6, 3'UTR 5, 5'Flank 4, In Frame Del 3.

Variants (750 of 2,430; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNAH5 | c.8998C>T p.R3000* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs769054713, BM1212176, COSV54207580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAL | c.733C>T p.R245* (on ENST00000269162 / NM_001142339.3; = p.R322* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as rs1252185897, CM135135, COSV52323513; ClinVar: pathogenic; called by muse, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 78/161 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SLC2A1 | c.517-1G>A p.X173_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as rs869312673, COSV100995758, COSV100995922, COSV65286764; ClinVar: pathogenic; called by muse, mutect2
- TP63 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs142762485, COSV53196450; called by muse, mutect2, varscan2
- A2ML1 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs201950472, COSV55286628; called by muse, mutect2
- AADAT | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV61786881; called by muse, mutect2, varscan2
- AAK1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68642074; called by muse, mutect2, varscan2
- ABCA9 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV60621305, COSV60623918; called by muse, mutect2, varscan2
- ABCB5 | c.3559G>A p.D1187N (on ENST00000404938 / NM_001163941.2; = p.D742N on NM_178559.6) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs759087816, COSV51703971; called by muse, mutect2, varscan2
- ABCC1 | c.4153C>T p.R1385* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs1479476888, COSV60681342; called by muse, mutect2, varscan2
- ABCC6 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.209); catalogued as rs1466190573, COSV52741687; called by muse, mutect2
- ABHD1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as COSV53204682; called by muse, mutect2, varscan2
- ABLIM3 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs750641202, COSV58639892; called by muse, mutect2, varscan2
- ABR | c.884C>T p.P295L (on ENST00000302538 / NM_021962.5; = p.P258L on NM_001092.5) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV52142271; called by muse, mutect2, varscan2
- AC005833.1 | c.1097G>A p.W366* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as COSV52895074; called by muse, mutect2, varscan2
- AC104452.1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.041); catalogued as COSV55533879; called by muse, mutect2, varscan2
- AC244197.3 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV61711453; called by muse, mutect2, varscan2
- ACAN | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs372286756, COSV61358491; called by muse, mutect2, varscan2
- ACD | c.1063C>A p.P355T (on ENST00000620338; = p.P266T on NM_022914.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV54666196; called by mutect2, varscan2
- ACIN1 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV52973764; called by muse, mutect2, varscan2
- ACP1 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs1222854326, COSV55242510; called by muse, mutect2, varscan2
- ACSM2A | c.1318G>A p.D440N (on ENST00000219054; = p.D361N on NM_001308169.2) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as COSV54582719, COSV54586323; called by muse, mutect2, varscan2
- ACSM2B | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV61656991; called by muse, mutect2, varscan2
- ACSS3 | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 116/367 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54086046; called by muse, mutect2, varscan2
- ACTB | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.638); catalogued as rs11546929, COSV59316533, COSV59317010, COSV59320272; called by muse, mutect2, varscan2
- ACTL7B | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146541685; called by muse, mutect2, varscan2
- ACTR5 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV54759978; called by muse, mutect2, varscan2
- ADAM18 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV55844402; called by muse, mutect2, varscan2
- ADAM29 | c.341T>A p.V114D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63660955, COSV63667882; called by muse, mutect2, varscan2
- ADAM32 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV65947464; called by mutect2, varscan2
- ADAM7 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911395416, COSV51535792; called by muse, mutect2, varscan2
- ADAMTS14 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1371462675, COSV64600016; called by muse, mutect2, varscan2
- ADAMTS18 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770516167, COSV51399705; called by muse, mutect2, varscan2
- ADAMTSL1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV52809544; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV54996936; called by muse, mutect2, varscan2
- ADAP2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779427042, COSV58295164; called by muse, varscan2
- ADARB2 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs377136355; called by mutect2, varscan2
- ADCY9 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.386); catalogued as COSV53572179; called by muse, mutect2, varscan2
- ADD2 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100036774, COSV52455725; called by muse, mutect2, varscan2
- ADGRB1 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs747412344, COSV60092580; called by mutect2, varscan2
- ADGRB3 | c.3814A>C p.K1272Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV53236234; called by muse, mutect2, varscan2
- ADGRG4 | c.7502C>T p.S2501L | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV54950755; called by muse, mutect2, varscan2
- ADGRL2 | c.3647G>A p.R1216K (on ENST00000370717 / NM_001366005.1; = p.R1160K on NM_012302.4) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1402606615, COSV54655320; called by muse, mutect2, varscan2
- ADRA2B | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1393193986, COSV69788315; called by mutect2, varscan2
- AFAP1L1 | c.1907T>C p.I636T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57044023; called by muse, mutect2, varscan2
- AFDN | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV60038741; called by muse, mutect2, varscan2
- AFF4 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.562); catalogued as COSV54792104; called by muse, mutect2, varscan2
- AGPS | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV51561492; called by muse, mutect2, varscan2
- AHNAK | c.11015C>T p.S3672F | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57205350; called by muse, varscan2
- AHNAK2 | c.9950C>T p.S3317L | Missense Mutation (SNP) | VAF 134/215 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs375227548; called by muse, mutect2, varscan2
- AHNAK2 | c.7771C>T p.P2591S | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV60909078; called by muse, mutect2, varscan2
- AICDA | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV57563598; called by mutect2, varscan2
- AK7 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV50869370, COSV50885870; called by muse, mutect2, varscan2
- AKAP13 | c.7387C>T p.R2463W (on ENST00000394518 / NM_007200.5; = p.R2467W on NM_006738.6) | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759792670, COSV63460455; called by muse, mutect2, varscan2
- AKNA | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV56311312; called by muse, mutect2, varscan2
- AKR1B10 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); catalogued as rs746697858, COSV62055053; called by muse, mutect2, varscan2
- AL669918.1 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV71270874, COSV71271138; called by muse, mutect2, varscan2
- ALG12 | c.1163-1G>A p.X388_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV58206364; called by muse, mutect2, varscan2
- ALG2 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs748614294, COSV53058826; ClinVar: uncertain significance; called by mutect2, varscan2
- ALK | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66559063; called by muse, mutect2, varscan2
- ALMS1 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs376632767, COSV52504065; called by mutect2, varscan2
- ALPK2 | c.6316A>C p.N2106H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64490613; called by muse, mutect2, varscan2
- ALPK2 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64490621; called by muse, mutect2, varscan2
- AMIGO3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV57537674; called by muse, mutect2, varscan2
- AMOT | c.1654G>A p.E552K (on ENST00000371959 / NM_001113490.1; = p.E143K on NM_133265.3) | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59060932; called by muse, mutect2, varscan2
- AMPD2 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1340521500, COSV56646460, COSV56650292; called by muse, mutect2, varscan2
- ANK1 | c.5063C>T p.T1688I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.177); catalogued as COSV55874705; called by muse, mutect2, varscan2
- ANK2 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002399, COSV52143804; called by muse, mutect2, varscan2
- ANK3 | c.12436G>A p.G4146R (on ENST00000280772 / NM_001320874.2; = p.G667R on NM_001149.3) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184370155, COSV55046788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.3986G>A p.R1329Q (on ENST00000280772 / NM_001320874.2; = p.R463Q on NM_001149.3) | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55046807; called by muse, mutect2, varscan2
- ANK3 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55046832; called by muse, mutect2, varscan2
- ANK3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55046849; called by muse, varscan2
- ANKEF1 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs773921192, COSV65692009; called by muse, mutect2, varscan2
- ANKEF1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145395317, COSV65691958; called by muse, mutect2, varscan2
- ANKFN1 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145812649, COSV59441961, COSV59455569; called by mutect2, varscan2
- ANKK1 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as COSV58270618; called by muse, varscan2
- ANKRD30A | c.1329A>C p.E443D (on ENST00000611781; = p.E387D on NM_052997.2) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as COSV64605209; called by muse, mutect2, varscan2
- ANKRD30A | c.2521G>A p.D841N (on ENST00000611781; = p.D785N on NM_052997.2) | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV100654373, COSV64605221; called by muse, mutect2, varscan2
- ANKRD30A | c.3148G>A p.E1050K (on ENST00000611781; = p.E994K on NM_052997.2) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1237785275, COSV64605238; called by muse, mutect2, varscan2
- ANKRD30A | c.3670C>T p.H1224Y (on ENST00000611781; = p.H1168Y on NM_052997.2) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV64605247; called by muse, mutect2, varscan2
- ANKRD36B | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51530612; called by muse, mutect2, varscan2
- ANO3 | c.1816A>T p.I606F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56782396; called by muse, mutect2, varscan2
- ANO4 | c.296A>G p.E99G (on ENST00000392977 / NM_001286615.2; = p.E64G on NM_178826.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54587414; called by muse, mutect2
- ANO5 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs752254981, COSV61082635; called by muse, mutect2, varscan2
- ANP32D | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV56980026, COSV56980054, COSV56980118; called by muse, mutect2, varscan2
- ANPEP | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV55589619; called by muse, mutect2, varscan2
- ANXA9 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV64484242; called by muse, mutect2, varscan2
- AOC3 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53824337; called by muse, mutect2, varscan2
- AP1M2 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs540463824, COSV51565669; called by muse, mutect2, varscan2
- APBA1 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV55222564; called by muse, mutect2, varscan2
- APC | c.4081C>T p.P1361S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57328023; called by muse, mutect2, varscan2
- APIP | c.58-1G>A p.X20_splice | Splice Site (SNP) | VAF 18/77 reads (23%) | catalogued as COSV53506100; called by muse, mutect2, varscan2
- APOB | c.3233G>A p.R1078K | Missense Mutation (SNP) | VAF 157/507 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.344); catalogued as COSV51925462; called by muse, mutect2, varscan2
- APOBR | c.3025C>T p.R1009C (on ENST00000431282; = p.R1018C on NM_018690.4) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs528190355, COSV60489033; called by mutect2, varscan2
- APOL4 | c.955G>A p.A319T (on ENST00000352371 / NM_145660.2; = p.A316T on NM_030643.4) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1168763718; called by muse, mutect2, varscan2
- AQP4 | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 48/161 reads (30%) | catalogued as COSV101270559, COSV67218294; called by muse, mutect2, varscan2
- AQR | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448725068, COSV50029970; called by mutect2, varscan2
- ARAP1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV61989735; called by muse, mutect2, varscan2
- ARHGAP44 | c.1154T>C p.L385S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52389807, COSV52392199; called by muse, mutect2, varscan2
- ARHGAP9 | c.2200C>T p.P734S (on ENST00000393797 / NM_001319850.2; = p.P715S on NM_032496.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV57358570; called by muse, mutect2, varscan2
- ARHGEF18 | c.3233C>T p.S1078F (on ENST00000359920 / NM_001130955.2; = p.S974F on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.096); catalogued as COSV100149750, COSV60467359; called by muse, mutect2, varscan2
- ARHGEF2 | c.398C>T p.S133F (on ENST00000361247 / NM_001162383.2; = p.S106F on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV58107243; called by muse, mutect2, varscan2
- ARMCX1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV65704933; called by muse, mutect2, varscan2
- ARPP21 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV51792987; called by muse, mutect2, varscan2
- ASB4 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57943304; called by muse, varscan2
- ASPRV1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57227504; called by muse, mutect2, varscan2
- ASXL2 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV55454440; called by muse, varscan2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ATF1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV50395433; called by muse, mutect2, varscan2
- ATG2A | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1400627481, COSV65966003; called by muse, mutect2, varscan2
- ATG2B | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63421932; called by muse, mutect2, varscan2
- ATP10A | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63514212; called by muse, mutect2, varscan2
- ATP10D | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV56704537; called by mutect2, varscan2
- ATP13A5 | c.3473G>A p.R1158K | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV53230231; called by muse, mutect2, varscan2
- ATP13A5 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as rs752547591, COSV60866400; called by muse, mutect2, varscan2
- ATP1A2 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV63402502; called by muse, mutect2, varscan2
- ATP1A4 | c.2970-1G>A p.X990_splice | Splice Site (SNP) | VAF 83/266 reads (31%) | catalogued as COSV63623927; called by muse, mutect2, varscan2
- ATP2A3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59228618; called by muse, mutect2, varscan2
- ATP5PB | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751833359, COSV52384704; called by muse, mutect2, varscan2
- ATP6V0A1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52871153; called by muse, mutect2, varscan2
- ATP8A2 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54939491; called by muse, mutect2, varscan2
- ATR | c.3892G>A p.D1298N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1406692405, COSV63384484, COSV63385273; called by muse, mutect2, varscan2
- ATXN3L | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 74/111 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV66075315; called by muse, mutect2, varscan2
- AVIL | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57680660; called by muse, mutect2, varscan2
- AWAT1 | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV65738254; called by muse, varscan2
- B3GNT2 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV57343982; called by muse, mutect2, varscan2
- B4GALNT4 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs1182527987, COSV57321932; called by muse, mutect2, varscan2
- BANP | c.1412C>T p.S471L (on ENST00000286122; = p.S421L on NM_017869.4) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs762891001, COSV53734248; called by mutect2, varscan2
- BARHL2 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV64980877; called by muse, mutect2, varscan2
- BARX2 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55649496; called by muse, mutect2, varscan2
- BCAT1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV53908186; called by muse, mutect2, varscan2
- BCL11B | c.1288G>A p.E430K (on ENST00000357195 / NM_001282237.2; = p.E359K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1208436010, COSV100595140, COSV61733810; called by mutect2, varscan2
- BCL9 | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 61/181 reads (34%) | catalogued as rs373321043, COSV52341603; called by muse, mutect2, varscan2
- BCO2 | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV63062681; called by muse, mutect2, varscan2
- BICD1 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV55675349; called by muse, varscan2
- BIRC6 | c.1696T>A p.C566S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs770358856, COSV70196141; called by muse, mutect2, varscan2
- BIRC6 | c.10976T>A p.I3659N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV70196142; called by muse, mutect2, varscan2
- BRICD5 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV57028022; called by muse, mutect2, varscan2
- BRINP2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV64175884, COSV64177184; called by muse, mutect2, varscan2
- BRIP1 | c.1797C>T p.A599= | Splice Region (SNP) | VAF 50/129 reads (39%) | catalogued as rs771672834, COSV51994811; called by muse, mutect2, varscan2
- BTBD11 | c.2326G>A p.E776K (on ENST00000280758 / NM_001018072.2; = p.E313K on NM_001017523.2) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.395); catalogued as COSV55018338; called by muse, varscan2
- C11orf53 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.051); catalogued as COSV54721046; called by muse, mutect2, varscan2
- C11orf54 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV58679465; called by muse, mutect2, varscan2
- C12orf50 | c.683A>T p.K228I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV53893698; called by mutect2, varscan2
- C16orf78 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs763622892, COSV100147571, COSV54555196; called by mutect2, varscan2
- C19orf44 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55610508; called by muse, mutect2, varscan2
- C19orf57 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV60967318; called by muse, mutect2, varscan2
- C1S | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61070225; called by muse, mutect2, varscan2
- C1orf87 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64596237; called by muse, mutect2, varscan2
- C20orf194 | c.2771A>T p.N924I | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52692264; called by muse, mutect2, varscan2
- C6 | c.887A>T p.N296I | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.178); catalogued as rs550564724, COSV54706166; called by muse, mutect2, varscan2
- C6 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706174; called by muse, varscan2
- C6orf58 | c.941T>G p.V314G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV61666068; called by muse, mutect2, varscan2
- C8B | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV64779036; called by muse, mutect2, varscan2
- C9orf131 | c.2349G>A p.W783* | Nonsense Mutation (SNP) | VAF 45/106 reads (42%) | catalogued as COSV56609831; called by muse, mutect2, varscan2
- C9orf135 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.934); catalogued as COSV65874657; called by muse, mutect2, varscan2
- CABP5 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV53152109; called by muse, varscan2
- CABS1 | c.228A>T p.K76N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV56733046; called by muse, mutect2, varscan2
- CACNA1E | c.4562T>A p.F1521Y | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62383999; called by mutect2, varscan2
- CACNA1I | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as COSV60802218; called by muse, mutect2, varscan2
- CACNA1S | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV62936849; called by muse, mutect2, varscan2
- CACNA2D3 | c.1249T>A p.F417I | Missense Mutation (SNP) | VAF 94/156 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV55518402; called by muse, mutect2, varscan2
- CADM2 | c.640C>T p.P214S (on ENST00000407528 / NM_001167674.2; = p.P216S on NM_153184.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.191); catalogued as COSV67359580; called by muse, mutect2, varscan2
- CADM3 | c.893G>A p.G298D (on ENST00000368125 / NM_001127173.3; = p.G332D on NM_021189.5) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV63684193; called by muse, mutect2, varscan2
- CAGE1 | c.541G>A p.E181K (on ENST00000512086; = p.E45K on NM_205864.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV57075022; called by mutect2, varscan2
- CALN1 | c.334G>A p.D112N (on ENST00000329008 / NM_001017440.3; = p.D154N on NM_031468.4) | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs748456626, COSV61121606; called by muse, mutect2, varscan2
- CAMKV | c.636C>T p.I212= | Splice Region (SNP) | VAF 39/55 reads (71%) | catalogued as COSV56554252; called by muse, mutect2, varscan2
- CAMSAP3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.834); catalogued as COSV50331277; called by muse, mutect2, varscan2
- CAPN10 | c.1944-1G>A p.X648_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54375062; called by muse, mutect2, varscan2
- CARNS1 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57047968; called by muse, mutect2, varscan2
- CASD1 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV51970965; called by muse, mutect2, varscan2
- CATSPERD | c.2336G>A p.R779K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV58464409; called by muse, mutect2, varscan2
- CBFB | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV51997002; called by muse, mutect2, varscan2
- CBLN2 | c.418A>G p.K140E | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV54050389; called by muse, mutect2, varscan2
- CC2D2B | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV60357330; called by muse, mutect2, varscan2
- CCDC105 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV52963305, COSV99479788; called by muse, mutect2, varscan2
- CCDC110 | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as COSV56869664; called by muse, mutect2, varscan2
- CCDC14 | c.788C>T p.S263L (on ENST00000488653; = p.S215L on NM_022757.5) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV59943234; called by muse, mutect2, varscan2
- CCDC150 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV55872229; called by muse, mutect2, varscan2
- CCDC6 | c.645T>A p.N215K | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54054955; called by muse, mutect2, varscan2
- CCDC60 | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV59540799; called by muse, mutect2, varscan2
- CCDC60 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772386912, COSV59540809; called by muse, mutect2, varscan2
- CCDC68 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV61603145; called by muse, mutect2, varscan2
- CCDC7 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.74); catalogued as COSV53227063; called by muse, mutect2, varscan2
- CCDC7 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV56537662; called by muse, mutect2, varscan2
- CCDC7 | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs780090041, COSV56537676; called by muse, mutect2, varscan2
- CCDC73 | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58796044; called by muse, mutect2, varscan2
- CCDC88C | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as COSV57795951; called by muse, mutect2, varscan2
- CCDC88C | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs1444058212, COSV57795960; called by muse, mutect2, varscan2
- CCDC9 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV55719791; called by muse, mutect2, varscan2
- CCL24 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1273897977, COSV56116037; called by muse, mutect2, varscan2
- CCNL2 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 31/60 reads (52%) | catalogued as COSV68766161; called by muse, mutect2, varscan2
- CCSER2 | c.1365A>T p.E455D | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as COSV56502190; called by mutect2, varscan2
- CD163 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373039092; called by muse, mutect2, varscan2
- CD163L1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.954); catalogued as rs1372828364, COSV58011979; called by muse, mutect2, varscan2
- CD48 | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV63566077; called by muse, mutect2, varscan2
- CD72 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52410353; called by muse, mutect2, varscan2
- CD86 | c.547G>A p.D183N (on ENST00000330540 / NM_175862.5; = p.D177N on NM_006889.4) | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); catalogued as rs867896306, COSV52605354, COSV52608274; called by muse, mutect2, varscan2
- CDC42EP4 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs745809418; called by muse, mutect2
- CDC5L | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as rs751926250, COSV65175150; called by muse, mutect2, varscan2
- CDCA7 | c.692C>T p.S231L (on ENST00000347703 / NM_145810.3; = p.S310L on NM_031942.5) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs1281948661, COSV100143754, COSV60719943; called by muse, mutect2, varscan2
- CDCP1 | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 128/199 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as COSV56104035; called by muse, mutect2, varscan2
- CDH13 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs1295342476, COSV51795892; called by muse, mutect2, varscan2
- CDH20 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as rs367601432, COSV53005591; called by mutect2, varscan2
- CDH9 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50254459; called by muse, mutect2, varscan2
- CDHR1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.184); catalogued as rs769702557, COSV60559901; called by mutect2, varscan2
- CDHR2 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs369655476; called by muse, mutect2, varscan2
- CDK14 | c.1081C>T p.H361Y (on ENST00000380050 / NM_001287135.2; = p.H343Y on NM_012395.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56025428; called by muse, mutect2, varscan2
- CDRT1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375199803; called by muse, varscan2
- CDSN | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV52537419; called by muse, mutect2, varscan2
- CDX2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66829239; called by muse, mutect2
- CEACAM20 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 91/362 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1018655741, COSV57600790; called by muse, mutect2, varscan2
- CEL | c.1727C>T p.P576L (on ENST00000673714; = p.P573L on NM_001807.6) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs766698174, COSV60826419; called by muse, varscan2
- CEMIP2 | c.3053A>G p.N1018S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65484317; called by muse, varscan2
- CENPE | c.2458C>G p.Q820E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV54376974, COSV54392133; called by muse, mutect2, varscan2
- CENPF | c.5291G>A p.G1764E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100871596; called by muse, mutect2, varscan2
- CEP170B | c.2494C>T p.P832S (on ENST00000453495; = p.P761S on NM_015005.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV69023452; called by muse, mutect2, varscan2
- CEP78 | c.1715C>T p.P572L (on ENST00000424347 / NM_001349840.2; = p.P573L on NM_032171.3) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52845730; called by muse, varscan2
- CEP85 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1359631322; called by muse, mutect2, varscan2
- CEP95 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782475306, COSV56748119; called by muse, mutect2, varscan2
- CERT1 | c.1921C>G p.R641G (on ENST00000405807 / NM_001130105.1; = p.R513G on NM_005713.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV54656028, COSV54662581; called by muse, mutect2, varscan2
- CES2 | c.1420+1G>A p.X474_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as rs776761761, COSV57696323; called by muse, mutect2, varscan2
- CFAP20DC | c.577G>A p.D193N (on ENST00000482387 / NM_001351530.2; = p.D68N on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs1298372008, COSV55916833; called by muse, mutect2, varscan2
- CFAP221 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV54654365; called by muse, mutect2, varscan2
- CFAP44 | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV55609150; called by muse, mutect2, varscan2
- CFAP58 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57211442; called by muse, mutect2, varscan2
- CHAF1A | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV56670560; called by muse, varscan2
- CHD4 | c.2126C>T p.T709I (on ENST00000357008 / NM_001363606.2; = p.T722I on NM_001273.5) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58895896; called by muse, mutect2, varscan2
- CHD6 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs775880254, COSV58554378; called by muse, mutect2, varscan2
- CHKA | c.293T>G p.F98C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55838693; called by muse, mutect2, varscan2
- CHRNB4 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV55714920; called by muse, mutect2, varscan2
- CIC | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs775018722, COSV99360423; called by muse, mutect2, varscan2
- CIT | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 93/277 reads (34%) | catalogued as COSV55861746; called by muse, mutect2, varscan2
- CLCN4 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 85/135 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV66465312; called by muse, varscan2
- CLDN16 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.112); catalogued as COSV53227054; called by muse, mutect2, varscan2
- CLDN18 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV59301649; called by muse, mutect2, varscan2
- CLDN6 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs1257079235, COSV58508983; called by muse, mutect2, varscan2
- CLEC5A | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV69396851; called by muse, mutect2
- CLMN | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.165); catalogued as COSV54179531; called by muse, mutect2, varscan2
- CLN8 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs759475160; called by muse, mutect2
- CLSTN2 | c.2213-1G>A p.X738_splice | Splice Site (SNP) | VAF 23/62 reads (37%) | catalogued as COSV71718485; called by muse, varscan2
- CLTC | c.647T>C p.F216S | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV52245299; called by muse, mutect2, varscan2
- CLU | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs1476182021, COSV57065881; called by mutect2, varscan2
- CMTM5 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.021); catalogued as COSV59304937; called by mutect2, varscan2
- CMYA5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV71404281; called by muse, mutect2, varscan2
- CNGA2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61703480; called by muse, mutect2, varscan2
- CNGB3 | c.1779C>T p.I593= | Splice Region (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60685589; called by mutect2, varscan2
- CNKSR1 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64162877; called by mutect2, varscan2
- CNOT1 | c.3866A>G p.N1289S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV55313763; called by muse, mutect2, varscan2
- CNTN2 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV59348406; called by muse, mutect2, varscan2
- CNTN5 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54285866; called by muse, mutect2, varscan2
- CNTN5 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as rs1385144818, COSV54282815, COSV99680319; called by muse, mutect2, varscan2
- CNTNAP3 | c.3698G>A p.G1233E | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.101); catalogued as COSV99904580; called by muse, varscan2
- CNTNAP3 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV52664441; called by muse, mutect2, varscan2
- CNTNAP5 | c.2303A>C p.D768A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV70475186; called by muse, mutect2, varscan2
- CNTROB | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1265643912, COSV66607667; called by muse, mutect2, varscan2
- COBL | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54339653; called by muse, mutect2, varscan2
- COG5 | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV51743739; called by muse, mutect2, varscan2
- COL11A1 | c.3070G>A p.G1024R | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62174641; called by muse, mutect2, varscan2
- COL11A1 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62174649; called by muse, mutect2, varscan2
- COL14A1 | c.4943C>T p.S1648F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1164225192; called by muse, mutect2, varscan2
- COL17A1 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV62225494; called by muse, varscan2
- COL19A1 | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100505704, COSV59566794; called by muse, mutect2
- COL1A1 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs199510546, COSV56802573; called by muse, mutect2, varscan2
- COL20A1 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs199598230, COSV58912614; called by muse, mutect2, varscan2
- COL21A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs267601087, COSV55152247; called by muse, mutect2, varscan2
- COL22A1 | c.3374C>T p.P1125L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs906340766, COSV57325816, COSV57329377; called by muse, mutect2, varscan2
- COL22A1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs868284308, COSV57325832; called by muse, mutect2, varscan2
- COL2A1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV61528385; called by muse, mutect2, varscan2
- COL3A1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58582898; called by muse, mutect2, varscan2
- COL4A4 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61629989; called by muse, mutect2, varscan2
- COL5A1 | c.4982G>A p.G1661E | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65665766; called by muse, mutect2, varscan2
- COL6A1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.109); catalogued as rs757791812, COSV62611723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.8182G>A p.E2728K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV55081325; called by muse, mutect2, varscan2
- COL6A3 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs777759049, COSV55081337; called by mutect2, varscan2
- COL7A1 | c.4417C>T p.P1473S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs768651065, COSV60391911; called by muse, mutect2, varscan2
- COL9A2 | c.891A>T p.K297N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV65607154; called by mutect2, varscan2
- COMMD8 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as rs1465722624, COSV67500255; called by muse, mutect2, varscan2
- CPA6 | c.89G>C p.S30T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV52722073, COSV52727795; called by muse, mutect2, varscan2
- CPNE7 | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV52011303; called by muse, mutect2
- CPS1 | c.3941C>T p.S1314F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51803481; called by muse, mutect2, varscan2
- CPSF1 | c.3446C>T p.P1149L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs868976243; called by muse, mutect2, varscan2
- CPT1C | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV54917912; called by muse, mutect2, varscan2
- CPZ | c.889G>A p.E297K (on ENST00000360986 / NM_001014447.3; = p.E286K on NM_003652.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100249317, COSV59921844; called by mutect2, varscan2
- CR1 | c.2717G>A p.R906K | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.91); catalogued as COSV65456335; called by muse, mutect2, varscan2
- CRACDL | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV67406766; called by muse, mutect2, varscan2
- CREB3L3 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as rs753953218, COSV99313944; called by muse, mutect2, varscan2
- CREBBP | c.569A>T p.N190I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV52115430; called by muse, mutect2, varscan2
- CRIM1 | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs200582106, COSV54860150; called by muse, mutect2, varscan2
- CRMP1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61478659; called by muse, mutect2, varscan2
- CRNKL1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs766122480, COSV55620920; called by muse, mutect2, varscan2
- CRYBG2 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV57483994; called by muse, varscan2
- CSMD1 | c.9529G>A p.E3177K (on ENST00000520002; = p.E3176K on NM_033225.6) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.988); catalogued as rs184090049, COSV59279519; called by mutect2, varscan2
- CSMD1 | c.6841G>A p.D2281N (on ENST00000520002; = p.D2280N on NM_033225.6) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59288692, COSV59383511; called by muse, mutect2
- CSMD2 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.464); catalogued as rs1391951449, COSV53885132; called by muse, mutect2, varscan2
- CSMD3 | c.5822G>A p.G1941E (on ENST00000297405 / NM_001363185.1; = p.G1837E on NM_052900.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52289908; called by muse, mutect2, varscan2
- CSMD3 | c.3872G>A p.G1291E (on ENST00000297405 / NM_001363185.1; = p.G1187E on NM_052900.3) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV52114275, COSV52269703; called by muse, mutect2
- CTC1 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751416791; called by muse, mutect2, varscan2
- CTC1 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.283); catalogued as COSV59852311; called by muse, mutect2, varscan2
- CTCFL | c.1676T>A p.I559N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54771411; called by muse, varscan2
- CTXN3 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.794); catalogued as rs747562833, COSV65218016; called by muse, mutect2, varscan2
- CUL9 | c.2749C>T p.L917F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV52725881, COSV52729749; called by muse, mutect2
- CUZD1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV59027436; called by muse, varscan2
- CWH43 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV56936587; called by muse, mutect2, varscan2
- CYB5R2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55085228; called by muse, mutect2, varscan2
- CYP1A2 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV59659132; called by muse, varscan2
- CYP2C19 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs767169643, COSV64906975; called by muse, mutect2, varscan2
- CYP2C9 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as rs1454934321, COSV53246978; called by muse, mutect2, varscan2
- CYP2E1 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53312441; called by muse, mutect2, varscan2
- CYP3A4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV60501115; called by muse, mutect2, varscan2
- CYP3A43 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55935211; called by muse, varscan2
- CYP46A1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as rs1304450322, COSV55893291; called by muse, mutect2, varscan2
- CYREN | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs371697903; called by muse, mutect2, varscan2
- CYTH4 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs753773355, COSV50631414; called by muse, mutect2, varscan2
- CYTH4 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as rs1039087659, COSV50631397, COSV50631425; called by muse, mutect2, varscan2
- DAB2IP | c.2927G>A p.G976E (on ENST00000408936; = p.G948E on NM_032552.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs995429854, COSV99035288; called by muse, mutect2, varscan2
- DAO | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.021); catalogued as COSV57321584; called by muse, mutect2, varscan2
- DAPL1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as rs769817629, COSV59353533; called by muse, mutect2, varscan2
- DBH | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs749447929, COSV55039955; called by muse, mutect2, varscan2
- DCC | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV71427234; called by muse, mutect2, varscan2
- DCD | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV53201171; called by muse, mutect2, varscan2
- DCLK3 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV69362390; called by muse, mutect2, varscan2
- DCTN1 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as rs910345597, COSV100720957; called by muse, mutect2, varscan2
- DCTN2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV54052052; called by muse, mutect2, varscan2
- DDC | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63564028; called by muse, mutect2, varscan2
- DDX23 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs768166264, COSV57282247; called by muse, mutect2, varscan2
- DDX23 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as rs747067894, COSV100339697, COSV57282259; called by muse, mutect2, varscan2
- DDX52 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1285215112; called by muse, mutect2, varscan2
- DDX60 | c.4087C>T p.P1363S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67095343; called by muse, mutect2, varscan2
- DDX60 | c.3581C>T p.T1194I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775193865, COSV67095350; called by muse, mutect2, varscan2
- DENND2A | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs918143759, COSV52048313; called by muse, mutect2, varscan2
- DESI2 | c.120T>A p.F40L | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV55640289; called by muse, mutect2, varscan2
- DGKG | c.2149G>A p.G717R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53962088; called by muse, mutect2, varscan2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs1259961080, COSV55934682; called by mutect2, varscan2
- DHX36 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs777634590, COSV57671154; called by muse, varscan2
- DHX8 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52251292; called by muse, mutect2, varscan2
- DLEU7 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs375022108, COSV68546621; called by mutect2, varscan2
- DLGAP1 | c.837G>A p.W279* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100230671; called by muse, mutect2, varscan2
- DLGAP2 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.594); catalogued as rs758756139, COSV70094902; called by muse, mutect2, varscan2
- DMAP1 | c.376T>G p.F126V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60000037; called by muse, mutect2, varscan2
- DMBT1 | c.5836C>T p.H1946Y (on ENST00000338354 / NM_001377530.1; = p.H1189Y on NM_004406.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV57536353; called by muse, mutect2, varscan2
- DMGDH | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1455517170, COSV54860743; called by muse, mutect2, varscan2
- DMKN | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.769); catalogued as COSV60084976; called by muse, mutect2, varscan2
- DMRT2 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs551354184, COSV52401039; called by muse, mutect2, varscan2
- DNAH10 | c.455C>T p.P152L (on ENST00000409039; = p.P91L on NM_207437.3) | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV68988942; called by muse, mutect2, varscan2
- DNAH10 | c.5250G>A p.W1750* (on ENST00000409039; = p.W1689* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV68988951; called by muse, mutect2, varscan2
- DNAH10 | c.10571C>T p.P3524L (on ENST00000409039; = p.P3463L on NM_207437.3) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV68988956; called by muse, mutect2, varscan2
- DNAH11 | c.4622G>A p.R1541Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs780372134, COSV60942462; called by muse, mutect2, varscan2
- DNAH11 | c.10448C>T p.A3483V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60942474; called by muse, mutect2, varscan2
- DNAH11 | c.10921G>A p.D3641N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV60942486; called by muse, mutect2, varscan2
- DNAH17 | c.13037C>T p.P4346L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs570056995; called by muse, mutect2, varscan2
- DNAH17 | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760905784, COSV67750388; called by mutect2, varscan2
- DNAH2 | c.6741+1G>A p.X2247_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | catalogued as COSV66717152; called by muse, varscan2
- DNAH3 | c.7852C>T p.R2618W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374594409, COSV54506757; called by muse, mutect2, varscan2
- DNAH5 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV54207626; called by muse, varscan2
- DNAH9 | c.4774G>A p.E1592K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV52337033; called by muse, mutect2, varscan2
- DNAJC10 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51136044; called by muse, mutect2, varscan2
- DNAJC13 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as rs761634420, COSV53446538; called by muse, mutect2, varscan2
- DNAJC28 | c.1008A>C p.R336S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV58721260; called by muse, mutect2, varscan2
- DNPEP | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 91/273 reads (33%) | catalogued as rs767299451, COSV56110257; called by muse, mutect2, varscan2
- DOCK1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54731670; called by muse, mutect2
- DOCK3 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV56506145; called by muse, mutect2, varscan2
- DOCK3 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV56506159; called by muse, mutect2, varscan2
- DOCK8 | c.3391-1G>A p.X1131_splice | Splice Site (SNP) | VAF 29/148 reads (20%) | catalogued as COSV66618192; called by muse, mutect2, varscan2
- DOCK8 | c.4777C>T p.P1593S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV66618199; called by muse, mutect2, varscan2
- DPYSL5 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.553); catalogued as COSV56509360; called by muse, mutect2, varscan2
- DRC7 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV61053300; called by muse, mutect2, varscan2
- DSC1 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV57142450; called by muse, mutect2, varscan2
- DSCAM | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68021908; called by mutect2, varscan2
- DSG1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 34/124 reads (27%) | catalogued as rs145081747, CM086709; called by muse, mutect2, varscan2
- DSG2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV55197290; called by muse, varscan2
- DSG2 | c.2029C>A p.Q677K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.011); catalogued as COSV55197303; called by muse, varscan2
- DSP | c.3209C>T p.S1070F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV65791478; called by muse, mutect2, varscan2
- DST | c.4337C>T p.A1446V (on ENST00000361203 / NM_001374722.1; = p.A1120V on NM_015548.5) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV55038387; called by muse, mutect2, varscan2
- DST | c.2378T>G p.L793R (on ENST00000361203 / NM_001374722.1; = p.L467R on NM_001723.6) | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55000658; called by muse, mutect2, varscan2
- DTX1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57495805; called by muse, mutect2, varscan2
- DUSP12 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV63411151; called by muse, mutect2, varscan2
- DUSP22 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs867349110, COSV60524181; called by muse, mutect2, varscan2
- DYSF | c.2481T>A p.N827K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.665); catalogued as COSV50273231; called by muse, mutect2, varscan2
- ECPAS | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1281731403, COSV99399213; called by muse, mutect2, varscan2
- EDARADD | c.220G>A p.G74R (on ENST00000334232 / NM_145861.4; = p.G64R on NM_080738.4) | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1044285599, COSV62061463; called by muse, mutect2, varscan2
- EFCAB2 | c.628G>A p.E210K (on ENST00000366522; = p.E74K on NM_032328.3) | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as rs557402578, COSV63655620; called by muse, mutect2, varscan2
- EFCAB3 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59500099; called by muse, mutect2, varscan2
- EGF | c.3372G>A p.G1124= | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as COSV54476227; called by muse, mutect2, varscan2
- EGFLAM | c.2911G>A p.E971K (on ENST00000354891 / NM_001205301.2; = p.E963K on NM_152403.4) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV59294308; called by muse, mutect2, varscan2
- EGR2 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.054); catalogued as COSV54346312; called by muse, mutect2, varscan2
- EHD4 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as rs932217428, COSV55003493; called by muse, mutect2, varscan2
- EIF3B | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV62803157; called by muse, mutect2, varscan2
- EIF3B | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs747838544, COSV62805126; called by muse, mutect2, varscan2
- ELMO1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV60296892; called by muse, mutect2, varscan2
- ELMOD1 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56191101; called by muse, mutect2, varscan2
- ELOA2 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as rs773426243, COSV55303678; called by muse, mutect2, varscan2
- ELOA3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV55294493; called by mutect2, varscan2
- ELP1 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs764797085, COSV65896475; called by muse, mutect2, varscan2
- EME1 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.325); catalogued as COSV56813804; called by muse, mutect2, varscan2
- ENDOV | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1317856593, COSV60496976; called by muse, mutect2, varscan2
- ENPP3 | c.1773G>T p.Q591H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62953174, COSV62956035; called by mutect2, varscan2
- ENPP4 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); catalogued as COSV58088348; called by muse, mutect2, varscan2
- ENTHD1 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs778890071, COSV57317651; called by muse, mutect2, varscan2
- ENTHD1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs577847629, COSV57317661; called by muse, mutect2, varscan2
- EPHA6 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV67561274; called by muse, mutect2, varscan2
- EPHA6 | c.2308G>A p.D770N (on ENST00000389672 / NM_001080448.3; = p.D162N on NM_173655.4) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67561283; called by muse, mutect2, varscan2
- EPHA7 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV65168724; called by muse, mutect2, varscan2
- EPHX2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV66844051, COSV66845453; called by muse, mutect2, varscan2
- EPS8L3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs781161635; called by muse, mutect2, varscan2
- ERBB4 | c.1984T>G p.F662V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV53506982, COSV53548835; called by muse, mutect2, varscan2
- ERC2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 96/145 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV55604343; called by muse, mutect2, varscan2
- ERC2 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV55604361; called by mutect2, varscan2
- ERC2 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs757289425, COSV55604382; called by muse, mutect2, varscan2
- ERMN | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV68075028; called by muse, mutect2, varscan2
- ERMP1 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV53036395; called by muse, varscan2
- ESRP1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 158/488 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs201610171, COSV64408140; called by muse, varscan2
- ESRP1 | c.1098T>A p.D366E | Missense Mutation (SNP) | VAF 131/409 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64408146; called by muse, mutect2, varscan2
- EZH2 | c.1590T>G p.C530W (on ENST00000460911 / NM_001203247.2; = p.C535W on NM_004456.5) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57447620; called by muse, mutect2, varscan2
- F11 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554083456, CM140268, COSV53001388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F5 | c.349A>T p.I117F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63121266; called by muse, mutect2, varscan2
- F8 | c.2987G>A p.R996K | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV64270152; called by muse, mutect2, varscan2
- FAAH2 | c.1014A>C p.E338D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV66505856; called by muse, mutect2, varscan2
- FAM111A | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.055); catalogued as COSV64655092; called by muse, mutect2, varscan2
- FAM135B | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52708540; called by muse, mutect2, varscan2
- FAM135B | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV52708563; called by muse, mutect2, varscan2
- FAM135B | c.2962A>C p.T988P | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); catalogued as COSV52708585; called by muse, mutect2, varscan2
- FAM135B | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs187739434, COSV52708604; called by mutect2, varscan2
- FAM171A1 | c.2132C>T p.S711F | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867331185, COSV65313805; called by muse, mutect2, varscan2
- FAM214A | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs896774244, COSV55922452, COSV55922818; called by muse, mutect2, varscan2
- FAM47C | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV63724111; called by muse, varscan2
- FAM71B | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 162/533 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV57227753; called by muse, mutect2, varscan2
- FAM71D | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.261); catalogued as COSV61294772; called by muse, mutect2, varscan2
- FAM9B | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | catalogued as COSV59119147; called by muse, mutect2, varscan2
- FARSA | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1039345146, COSV58904449; called by muse, mutect2, varscan2
- FASTKD2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV52697525; called by muse, mutect2, varscan2
- FAT1 | c.12872C>T p.S4291F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV71672247; called by muse, mutect2, varscan2
- FBLN1 | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs267606275, COSV59936514; called by muse, mutect2, varscan2
- FBLN5 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV50902224; called by muse, mutect2, varscan2
- FBN1 | c.5569C>G p.P1857A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV57310705; called by muse, mutect2, varscan2
- FBXL18 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs768118907, COSV66665434; called by muse, varscan2
- FBXL4 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57745201; called by muse, mutect2, varscan2
- FBXO24 | c.659C>T p.A220V (on ENST00000241071 / NM_033506.3; = p.A258V on NM_012172.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.045); catalogued as COSV53824105; called by muse, mutect2, varscan2
- FBXW10 | c.1525G>T p.V509L | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV57315238; called by muse, mutect2, varscan2
- FBXW8 | c.1357C>T p.R453C (on ENST00000309909; = p.R491C on NM_012174.1) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs569559960, COSV59296965; called by muse, mutect2
- FCER1A | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as COSV63666629; called by muse, mutect2, varscan2
- FCMR | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV54320056; called by muse, mutect2, varscan2
- FCRL3 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV63839804; called by muse, mutect2, varscan2
- FCRL3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV63839813; called by muse, mutect2, varscan2
- FER1L5 | c.5953A>T p.N1985Y (on ENST00000623019; = p.N1949Y on NM_001293083.2) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53840727; called by mutect2, varscan2
- FETUB | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54004890, COSV99409130; called by muse, mutect2, varscan2
- FETUB | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54005394; called by muse, mutect2, varscan2
- FETUB | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54005683; called by muse, mutect2, varscan2
- FGF23 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV52975236; called by muse, mutect2, varscan2
- FGF6 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1448230216, COSV57403639; called by muse, mutect2, varscan2
- FGFR1 | c.1255A>G p.K419E (on ENST00000447712 / NM_023110.3; = p.K417E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV58329157; called by muse, mutect2, varscan2
- FGFR1 | c.925C>T p.Q309* (on ENST00000447712 / NM_023110.3; = p.Q307* on NM_015850.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as CM133687, COSV58329186, COSV58332078; called by muse, mutect2, varscan2
- FHL5 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV58735531; called by muse, mutect2, varscan2
- FIBP | c.715C>T p.Q239* (on ENST00000338369 / NM_198897.2; = p.Q232* on NM_004214.5) | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as COSV57171772; called by muse, varscan2
- FLG | c.10033G>A p.G3345R | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353933532, COSV64237645; called by muse, mutect2, varscan2
- FLG | c.9592G>A p.V3198I | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64237651; called by muse, mutect2, varscan2
- FLG | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV64237662; called by muse, mutect2, varscan2
- FLG2 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs755946938, COSV66166962; called by muse, mutect2, varscan2
- FLNC | c.7289C>T p.A2430V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.752); catalogued as rs200516164, CM1413292, COSV100368938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV56719510, COSV56746348; called by muse, mutect2, varscan2
- FMN2 | c.5043A>C p.K1681N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60419364; called by muse, mutect2, varscan2
- FMO1 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV61444812; called by muse, mutect2, varscan2
- FOXH1 | c.1036A>T p.S346C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as CM082690, COSV56760151; called by muse, mutect2, varscan2
- FOXM1 | c.1997G>A p.S666N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV61205386; called by muse, mutect2, varscan2
- FOXN2 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61317202; called by muse, mutect2, varscan2
- FOXO4 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV58574844; called by muse, varscan2
- FPGT | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs771587537; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1327859465, COSV58547046; called by muse, varscan2
- FRS3 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.727); catalogued as rs1193459126, COSV52484133; called by muse, mutect2, varscan2
- FSIP1 | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV63223594; called by muse, mutect2, varscan2
- FSIP2 | c.15971A>G p.K5324R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1185113302, COSV58079579; called by muse, varscan2
- FSTL5 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV60183341; called by muse, mutect2, varscan2
- FUT1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV59567581; called by mutect2, varscan2
- FUT9 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs781231611, COSV56150717; called by muse, mutect2, varscan2
- FUT9 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56150727; called by muse, mutect2, varscan2
- FYB2 | c.1817G>A p.W606* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | catalogued as COSV58583202; called by muse, mutect2, varscan2
- GABRA1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.88); catalogued as rs146134200; called by muse, varscan2
- GABRB3 | c.836-1G>A p.X279_splice | Splice Site (SNP) | VAF 37/107 reads (35%) | catalogued as COSV54652412, COSV54689872; called by muse, mutect2, varscan2
- GABRB3 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54652433; called by muse, mutect2, varscan2
- GABRE | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.264); catalogued as rs887036619, COSV64819010; called by muse, mutect2, varscan2
- GALNT10 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs754240894, COSV51721436; called by mutect2, varscan2
- GALNT12 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV66662224; called by muse, mutect2, varscan2
- GALNT17 | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV61149877; called by muse, mutect2, varscan2
- GALNTL5 | c.15A>G p.I5M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV67179434, COSV67180383; called by muse, mutect2, varscan2
- GALNTL6 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs146923140; called by muse, mutect2, varscan2
- GARRE1 | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV55097059; called by muse, mutect2, varscan2
- GAS2L3 | c.1201A>G p.N401D | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57156315; called by muse, mutect2, varscan2
- GCAT | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV50648679; called by muse, mutect2, varscan2
- GCKR | c.285+1G>A p.X95_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as rs1360985123, COSV53020786; called by muse, mutect2, varscan2
- GCNT3 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV68531970; called by muse, mutect2, varscan2
- GCNT3 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 73/228 reads (32%) | catalogued as COSV68531973; called by muse, mutect2, varscan2
- GDA | c.1135+1G>A p.X379_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52990760; called by muse, mutect2, varscan2
- GHR | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV50106958; called by mutect2, varscan2
- GIMAP1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as rs758913531, COSV56187257; called by muse, mutect2, varscan2
- GIMAP8 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as COSV56230004; called by muse, mutect2, varscan2
- GJB4 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58355602; called by muse, mutect2, varscan2
- GK2 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs867193773; called by muse, mutect2, varscan2
- GLRA2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1187324711, COSV54336546; called by muse, mutect2, varscan2
- GLYATL2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs950923423, COSV54849193; called by muse, mutect2, varscan2
- GNL3 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66920827; called by muse, mutect2, varscan2
- GNRH2 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.168); catalogued as COSV55661401; called by muse, mutect2, varscan2
- GOLGA3 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV52626432; called by muse, mutect2
- GOLM2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV55461860; called by muse, mutect2
- GOLT1B | c.272T>G p.I91S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV57553040; called by muse, mutect2, varscan2
- GOT1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1254003405, COSV65147099; called by muse, mutect2, varscan2
- GP2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV56892330; called by muse, mutect2
- GPC6 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.383); catalogued as COSV65500081; called by muse, mutect2, varscan2
- GPR141 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759565313, COSV57731278, COSV57732248; called by muse, mutect2, varscan2
- GPR155 | c.2435G>A p.G812E | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55037659; called by muse, mutect2, varscan2
- GPR174 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs866013451, COSV52131618; called by muse, mutect2, varscan2
- GPR179 | c.3512G>A p.R1171Q (on ENST00000621958; = p.R1170Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs531239274; called by muse, mutect2, varscan2
- GPR26 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs757161262, COSV52932861; called by mutect2, varscan2
- GPR37 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58255649; called by muse, mutect2, varscan2
- GPR87 | c.419A>T p.Y140F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV53462385; called by muse, mutect2, varscan2
- GPRC5C | c.421G>A p.G141R (on ENST00000652232; = p.G96R on NM_018653.4) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV61235570; called by muse, mutect2, varscan2
- GPRC6A | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV59951504; called by muse, mutect2, varscan2
- GPRIN2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV65400537; called by mutect2, varscan2
- GRB7 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.608); catalogued as rs1352712833; called by muse, mutect2, varscan2
- GRIA1 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.038); catalogued as COSV53590941; called by muse, mutect2, varscan2
- GRIA2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV52383846; called by muse, mutect2, varscan2
- GRIK1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759536753, COSV58711902; called by mutect2, varscan2
- GRIK2 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV59715122; called by mutect2, varscan2
- GRIK2 | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59715149; called by muse, mutect2, varscan2
- GRIK3 | c.2584G>A p.V862M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs182190841; called by mutect2, varscan2
- GRIK3 | c.515G>A p.W172* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV66136182; called by muse, mutect2, varscan2
- GRIN2A | c.3385C>T p.H1129Y | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.307); catalogued as COSV58022657; called by muse, mutect2, varscan2
- GRIN2B | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1156304737; called by muse, varscan2
- GRIN2C | c.1304G>A p.R435K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53110336; called by muse, mutect2, varscan2
- GRK2 | c.1891A>T p.I631F | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV57750994; called by muse, mutect2, varscan2
- GRM3 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as COSV64467928; called by muse, mutect2, varscan2
- GRM3 | c.2543G>A p.G848E | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs144976488, COSV64467933; called by muse, mutect2, varscan2
- GRM6 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs145110689; called by muse, mutect2, varscan2
- GRM8 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV58806342; called by muse, mutect2, varscan2
- GRXCR1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV67670411; called by muse, mutect2, varscan2
- GSK3B | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as COSV51771368; called by muse, varscan2
- GTDC1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV53989030; called by muse, mutect2, varscan2
- GUCY2C | c.2734C>T p.L912F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53787355; called by muse, mutect2, varscan2
- HAGH | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68400238; called by muse, mutect2, varscan2
- HAS1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748560541, COSV55786420; called by muse, mutect2, varscan2
- HASPIN | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV53990068; called by muse, mutect2
- HCAR2 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61024395; called by muse, mutect2, varscan2
- HCN2 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV52112781; called by muse, mutect2, varscan2
- HEATR5B | c.5765C>T p.P1922L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs751126880, COSV51849652, COSV51860424; called by muse, mutect2, varscan2
- HELZ2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.039); catalogued as COSV64409163; called by muse, mutect2, varscan2
- HEPH | c.3080G>A p.G1027E (on ENST00000343002; = p.G760E on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228570929, COSV57960003, COSV57972321; called by muse, mutect2, varscan2
- HEPHL1 | c.2728G>A p.G910R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV59889834; called by muse, mutect2, varscan2
- HEPHL1 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV59889838; called by muse, varscan2
- HK1 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs753390525, COSV53852729; called by muse, mutect2, varscan2
- HM13 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV59435900; called by muse, mutect2, varscan2
- HMCN1 | c.7843C>T p.P2615S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as COSV54881136; called by muse, mutect2, varscan2
- HMCN1 | c.11765G>A p.G3922E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54881151; called by muse, mutect2, varscan2
- HMCN1 | c.14120C>T p.A4707V | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV54881162; called by muse, mutect2, varscan2
- HMGCLL1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV51441184; called by mutect2, varscan2
- HMSD | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.534); catalogued as COSV68816809; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.911G>A p.G304E (on ENST00000354667 / NM_031243.3; = p.G292E on NM_002137.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61158212, COSV61160762; called by muse, mutect2, varscan2
- HOXB1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV53316550; called by muse, mutect2, varscan2
- HOXB13 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.881); catalogued as COSV51705507; called by muse, mutect2, varscan2
- HOXB3 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV57485987; called by muse, mutect2, varscan2
- HOXC5 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.039); catalogued as COSV54536354; called by muse, mutect2, varscan2
- HPS5 | c.778T>C p.F260L (on ENST00000349215 / NM_181507.2; = p.F146L on NM_007216.4) | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62538788; called by muse, mutect2, varscan2
- HS6ST3 | c.708G>A p.R236= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65003096; called by muse, mutect2, varscan2
- HSD17B4 | c.1643T>C p.L548P (on ENST00000414835 / NM_001199291.3; = p.L523P on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs910573226, COSV56333975; called by muse, mutect2, varscan2
- HSPG2 | c.11830C>T p.L3944F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113130096; called by mutect2, varscan2
- HSPG2 | c.10574T>C p.V3525A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65932773; called by muse, mutect2, varscan2
- HTT | c.3188C>T p.T1063I | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV61858166; called by muse, mutect2, varscan2
- HYDIN | c.261G>A p.K87= | Splice Region (SNP) | VAF 36/161 reads (22%) | catalogued as COSV55478775; called by muse, mutect2, varscan2
- HYKK | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1256839159; called by muse, varscan2
- IFNA13 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV101489513; called by muse, varscan2
- IGF1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs1316717107, COSV61031712; called by muse, varscan2
- IGFL2 | c.166G>A p.A56T (on ENST00000377693 / NM_001135113.2; = p.A67T on NM_001002915.2) | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs754195953, COSV66616668; called by muse, mutect2, varscan2
- IGFL2 | c.338A>T p.E113V (on ENST00000377693 / NM_001135113.2; = p.E124V on NM_001002915.2) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV66616673; called by muse, mutect2, varscan2
- IGHM | c.315G>A p.V105= | Splice Region (SNP) | VAF 24/34 reads (71%) | catalogued as rs782092025; called by muse, mutect2, varscan2
- IGHV1-2 | c.244A>T p.K82* | Nonsense Mutation (SNP) | VAF 86/139 reads (62%) | catalogued as rs575477620; called by muse, mutect2, varscan2
- IGHV3-7 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs528253327; called by muse, mutect2, varscan2
- IGLON5 | c.497G>A p.W166* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV54534762; called by muse, mutect2
- IGSF1 | c.3017G>A p.G1006E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as rs777039530, CX164156, COSV100812068, COSV63836412; called by muse, mutect2, varscan2
- IKBKB | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV60596038, COSV60598980; called by muse, mutect2, varscan2
- IKZF1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58781844; called by mutect2, varscan2
- IL18R1 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs867487527, COSV52122470; called by muse, mutect2, varscan2
- IL1A | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.237); catalogued as rs1212336544, COSV54519005; called by muse, mutect2, varscan2
- IL1RL1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.253); catalogued as COSV52111916; called by muse, mutect2, varscan2
- IL1RL1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as rs372144350; called by muse, mutect2
- IL27RA | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.062); catalogued as rs148333746, COSV54599327; called by muse, mutect2, varscan2
- IMPA1 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.997); catalogued as COSV56270447, COSV99808873; called by muse, mutect2, varscan2
- IMPACT | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | catalogued as rs1220916989, COSV52421357; called by muse, mutect2, varscan2
- IMPG1 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV64054658; called by muse, varscan2
- INSIG1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs527701821, COSV60919876; called by muse, mutect2, varscan2
- INTS13 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267603432, COSV53901406; called by muse, mutect2
- INTS8 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58248985; called by muse, mutect2, varscan2
- INTU | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV56538461; called by muse, mutect2, varscan2
- IPO5 | c.3070C>T p.H1024Y | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV55152412; called by muse, mutect2, varscan2
- IQCC | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as COSV52207790; called by muse, mutect2, varscan2
- IQCD | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55320491; called by muse, mutect2, varscan2
- IQGAP2 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 23/132 reads (17%) | catalogued as rs192694811, CM157664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRAG2 | c.3751G>A p.D1251N (on ENST00000636465; = p.D296N on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV63137716; called by muse, mutect2, varscan2
- IRF3 | c.722G>A p.W241* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV55862443; called by muse, mutect2, varscan2
- ITGA1 | c.2795C>T p.T932I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV50876789, COSV50877366; called by muse, mutect2, varscan2
- ITGA8 | c.2869A>G p.T957A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV65225417; called by muse, mutect2, varscan2
- ITGAD | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV66756954; called by muse, mutect2, varscan2
- ITGAX | c.3230C>T p.S1077F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV51642267; called by muse, mutect2, varscan2
- ITLN1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV58274035; called by muse, mutect2, varscan2
- ITSN2 | c.4748C>T p.A1583V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV61944170; called by muse, mutect2, varscan2
- IVL | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); catalogued as rs549912790, COSV64215662; called by muse, mutect2, varscan2
- JAG2 | c.3680G>A p.R1227K | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV59307000; called by muse, mutect2, varscan2
- JAK2 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV67583066; called by muse, mutect2, varscan2
- JAKMIP3 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53820532; called by muse, mutect2, varscan2
- JMJD1C | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as COSV59513209; called by muse, mutect2, varscan2
- JPH1 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV60609019; called by muse, mutect2, varscan2
- KCNA10 | c.1145T>G p.L382R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63904270; called by muse, mutect2, varscan2
- KCNA4 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60250901, COSV60253545; called by muse, mutect2, varscan2
- KCNA5 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV52904045; called by muse, mutect2, varscan2
- KCNC3 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV65386811; called by muse, mutect2, varscan2
- KCNF1 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.06); catalogued as COSV54462207; called by muse, mutect2, varscan2
- KCNH4 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV52915774; called by muse, mutect2, varscan2
- KCNH5 | c.2835A>T p.K945N | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.071); catalogued as COSV59753795; called by muse, mutect2, varscan2
- KCNH5 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59753801; called by muse, mutect2, varscan2
- KCNH7 | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59787696; called by muse, mutect2, varscan2
- KCNH7 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.166); catalogued as rs375588527, COSV59787711; called by muse, mutect2, varscan2
- KCNK10 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56640184; called by muse, mutect2, varscan2
- KDM3B | c.3631C>T p.P1211S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV58688431; called by muse, mutect2, varscan2
- KDM5B | c.3182C>T p.T1061I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV52504918; called by muse, mutect2, varscan2
- KDM5B | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1370386391, COSV52504927; called by muse, mutect2, varscan2
- KDM6B | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV99641154; called by mutect2, varscan2
- KDM6B | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV99641156; called by muse, mutect2, varscan2
- KIAA0100 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV66490931; called by muse, mutect2
- KIAA0319L | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs780120294; called by muse, mutect2, varscan2
- KIAA0513 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV50740695, COSV50742974; called by muse, mutect2, varscan2
- KIAA0586 | c.2551C>T p.P851S (on ENST00000619416 / NM_001244190.2; = p.P790S on NM_014749.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54171862; called by muse, mutect2, varscan2
- KIAA1522 | c.1085C>T p.S362F (on ENST00000373480 / NM_001198972.2; = p.S421F on NM_020888.3) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53862734; called by muse, mutect2, varscan2
- KIF12 | c.1840G>A p.A614T (on ENST00000640217; = p.A476T on NM_138424.1) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.088); catalogued as COSV65116745; called by muse, varscan2
- KIF13A | c.1867A>G p.M623V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV52444373; called by muse, mutect2, varscan2
- KIF5B | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56651177; called by muse, mutect2, varscan2
- KIF5C | c.776T>C p.L259S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68480056; called by muse, mutect2, varscan2
- KIF5C | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as rs949930083, COSV68480062; called by mutect2, varscan2
- KIFBP | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62555290; called by muse, mutect2, varscan2
- KIR2DL4 | c.981+1G>A p.X327_splice (on ENST00000396284; = p.X253_splice on NM_001080770.2) | Splice Site (SNP) | VAF 30/126 reads (24%) | catalogued as COSV58488408; called by muse, mutect2, varscan2
- KL | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66308027; called by muse, mutect2, varscan2
- KLF12 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV66570199; called by muse, mutect2, varscan2
- KLHDC7A | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1252925653; called by muse, mutect2, varscan2
- KLK1 | c.326A>C p.H109P | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); catalogued as COSV56826075; called by muse, varscan2
- KLK1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1488531020, COSV56826084; called by muse, mutect2, varscan2
- KLK6 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV59565107; called by muse, varscan2
- KLK8 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV51590386, COSV51590839; called by muse, mutect2, varscan2
- KMT2C | c.12227G>C p.R4076T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV51345727; called by muse, mutect2, varscan2
- KMT2D | c.7942C>T p.P2648S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); catalogued as COSV56415568; called by muse, varscan2
- KNL1 | c.1322C>T p.S441F (on ENST00000346991 / NM_170589.5; = p.S415F on NM_144508.5) | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV61151764, COSV61161448; called by muse, mutect2, varscan2
- KNSTRN | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs745844593, COSV51103672; called by muse, mutect2, varscan2
- KRT1 | c.691T>A p.F231I | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52865231; called by muse, mutect2, varscan2
- KRT12 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | catalogued as rs1266988580, COSV52429656; called by muse, mutect2, varscan2
- KRT36 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.392); catalogued as COSV60202657; called by muse, mutect2, varscan2
- KRT36 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60202662; called by muse, mutect2, varscan2
- KRT6C | c.1109A>C p.H370P | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1396038226, COSV52876686; called by muse, mutect2, varscan2
- KRT82 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV57785487; called by muse, mutect2, varscan2
- KRT86 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as rs370858159, COSV99525046; called by muse, mutect2, varscan2
- KRTAP1-1 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV60397958; called by muse, mutect2, varscan2
- KRTAP10-4 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs267606161, COSV59953808; called by muse, mutect2, varscan2
- KRTAP10-9 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV59953814, COSV59982246; called by muse, mutect2, varscan2
- KRTAP26-1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62128537, COSV62128816; called by muse, mutect2
- KRTAP27-1 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV67000927; called by muse, mutect2, varscan2
- KRTAP5-5 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.703); catalogued as COSV68784389; called by muse, varscan2
- KSR2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs548971268, COSV100351462, COSV60366465, COSV60384960; called by muse, mutect2, varscan2
- LAMC3 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs45444592; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- LAMP1 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV58148778; called by muse, mutect2, varscan2
- LARS1 | c.3380G>A p.R1127Q (on ENST00000394434 / NM_020117.11; = p.R1100Q on NM_016460.3) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs779368854, COSV50972554; called by mutect2, varscan2
- LHX4 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV55373386; called by muse, mutect2, varscan2
- LHX9 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61327318; called by muse, mutect2, varscan2
- LILRA1 | c.247T>C p.F83L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as rs1568538729, COSV52178622; called by muse, varscan2
- LILRA2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52188622; called by muse, mutect2, varscan2
- LILRB1 | c.656C>T p.S219F (on ENST00000427581; = p.S183F on NM_006669.6) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV61116350; called by muse, mutect2, varscan2
- LINGO4 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63213938; called by muse, mutect2, varscan2
- LMBRD2 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56948873; called by muse, mutect2, varscan2
- LNPEP | c.2992C>T p.R998C | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1047945256, COSV51476572; called by muse, mutect2, varscan2
- LOXL4 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230654492, COSV99584115; called by muse, mutect2, varscan2
- LOXL4 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037049191, COSV53254944; called by muse, varscan2
- LRGUK | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV53634684; called by muse, mutect2
- LRIT2 | c.642T>A p.F214L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV60559914; called by muse, mutect2, varscan2
- LRP1 | c.11774C>T p.S3925F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.928); catalogued as COSV54503434; called by muse, mutect2, varscan2
- LRP10 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62077768; called by muse, mutect2, varscan2
- LRP1B | c.13001C>T p.S4334L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV67191718; called by muse, mutect2, varscan2
- LRP1B | c.9583C>T p.H3195Y | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV101253763, COSV67191721; called by muse, mutect2, varscan2
- LRP1B | c.8782A>T p.N2928Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV67191724; called by mutect2, varscan2
- LRP1B | c.8567G>A p.R2856Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs777653737, COSV101256763, COSV67191728; called by muse, mutect2, varscan2
- LRP1B | c.5602C>T p.Q1868* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as COSV67191733; called by muse, mutect2, varscan2
- LRP2 | c.8891G>A p.R2964K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1451168947, COSV55543273; called by muse, mutect2, varscan2
- LRRC74A | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.189); catalogued as COSV53608107; called by muse, mutect2, varscan2
- LRRIQ1 | c.3809C>T p.S1270F | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV67826713; called by muse, mutect2, varscan2
- LRRN1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60012627; called by muse, mutect2, varscan2
- LRTM1 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs200529761, COSV55518412; called by muse, mutect2, varscan2
- LTBP2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV56205614; called by muse, mutect2, varscan2
- LUC7L2 | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as COSV54923959; called by muse, mutect2, varscan2
- LYVE1 | c.590A>T p.K197I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.078); catalogued as COSV56282261; called by mutect2, varscan2
- LZTFL1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV56110990; called by muse, mutect2, varscan2
- MAB21L1 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59763653, COSV59767612; called by muse, mutect2, varscan2
- MAEL | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs758058554, COSV63112323; called by muse, mutect2, varscan2
- MAGEA1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63118278; called by muse, mutect2, varscan2
- MAGEA10 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54883060; called by muse, mutect2, varscan2
- MAGEB18 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57463452; called by muse, mutect2, varscan2
- MAGEB6 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV66871964; called by muse, mutect2, varscan2
- MAGEC1 | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.213); catalogued as rs150635296, COSV53568958; called by muse, varscan2
- MAGEC1 | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 86/150 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV53568967; called by muse, mutect2, varscan2
- MAGI1 | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV58316520, COSV58350470; called by muse, mutect2, varscan2
- MAGI1 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58316542; called by muse, mutect2, varscan2
- MAGI1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.341); catalogued as COSV58316566; called by muse, mutect2, varscan2
- MAK16 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64078093; called by muse, mutect2, varscan2
- MAMDC4 | c.2200C>T p.P734S (on ENST00000445819; = p.P655S on NM_206920.3) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58070261; called by muse, mutect2, varscan2
- MAP11 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV57585389; called by muse, mutect2, varscan2
- MAP1A | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV55806624; called by muse, mutect2, varscan2
- MAP1B | c.5252C>T p.S1751F | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV57094653; called by muse, mutect2, varscan2
- MAP3K15 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751391076, COSV58826590; called by muse, mutect2, varscan2
- MAP4K5 | c.2138C>G p.S713C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50152833; called by muse, mutect2, varscan2
- MAPK11 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV57996499; called by muse, mutect2
- MAPK7 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55189570; called by muse, mutect2, varscan2
- MARCHF10 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1304517356, COSV60884991; called by muse, mutect2, varscan2
- MAS1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.254); catalogued as rs1440765163, COSV53120592; called by muse, mutect2, varscan2
- MAT1A | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64744838; called by muse, mutect2, varscan2
- MCC | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV56724646; called by muse, mutect2, varscan2
- MCF2L2 | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1261668249, COSV61049947; called by muse, mutect2, varscan2
- MCTP2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV59141454; called by muse, varscan2
- ME2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.162); catalogued as COSV58422435; called by muse, mutect2, varscan2
- MED12L | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV56370257; called by muse, mutect2, varscan2
- MEF2D | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV61727113; called by muse, mutect2, varscan2
- MEGF10 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV57245575; called by muse, mutect2, varscan2
- MEI1 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs1182311137, COSV55901203, COSV55901796, COSV55902853; called by muse, mutect2, varscan2
- MEP1B | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as rs201834412, COSV52495894; called by mutect2, varscan2
- MEP1B | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs553982727, COSV52495911; called by mutect2, varscan2
- MEPCE | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV52768787; called by muse, mutect2, varscan2
- MFSD14A | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 36/123 reads (29%) | catalogued as COSV54926732; called by muse, mutect2, varscan2
- MGAM | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV71885040, COSV71885999; called by muse, mutect2, varscan2
- MIA3 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 118/424 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV60510385; called by muse, mutect2, varscan2
- MICU3 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58845046; called by muse, mutect2, varscan2
- MLH3 | c.4267C>T p.R1423C (on ENST00000355774 / NM_001040108.2; = p.R1399C on NM_014381.3) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1278350332, COSV53152650; called by muse, mutect2, varscan2
- MMP2 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1196485000, COSV54599322; called by mutect2, varscan2
- MORC1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV51715216; called by muse, mutect2, varscan2
- MORC2 | c.2660C>T p.S887F (on ENST00000397641 / NM_001303256.3; = p.S825F on NM_014941.3) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53196594, COSV99063091; called by muse, mutect2, varscan2
- MOV10L1 | c.3258G>A p.M1086I | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53167941, COSV99434739; called by muse, mutect2, varscan2
- MR1 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1259828561, COSV51579950; called by muse, mutect2, varscan2
- MROH2B | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368507319; called by muse, mutect2, varscan2
- MROH2B | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as rs1036570558, COSV68181125, COSV68181709; called by muse, mutect2
- MRPL1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59673416; called by muse, mutect2, varscan2
- MRPL21 | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54820446; called by muse, mutect2, varscan2
- MSLN | c.1517C>T p.S506F (on ENST00000382862 / NM_013404.4; = p.S498F on NM_005823.6) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs761739553, COSV53499657; called by muse, mutect2, varscan2
- MSR1 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.758); catalogued as COSV50507335, COSV50508675; called by muse, varscan2
- MT1F | c.65A>C p.K22T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs745629607, COSV57622025; called by muse, mutect2, varscan2
- MTUS2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.447); catalogued as COSV70914182; called by mutect2, varscan2
- MUC15 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV55552569; called by muse, varscan2
- MUC16 | c.39140T>C p.L13047P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV67448787; called by muse, mutect2, varscan2
- MUC16 | c.30998C>T p.S10333F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as rs377478364; called by muse, mutect2, varscan2
1,680 further variants in this file (814 protein-altering or splice-affecting, 803 silent, 63 other) are not listed here.
